Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2OW, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2OW-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Gender: F

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Ordering

MD:

Copy To:

HPA Discrepancy		☒
Reviewed	8/31/11	8/18/11

Specimen(s) Received

1. Thyroid: RT.hemithyroid, stitch - rt. upper lobe

Diagnosis

Multifocal papillary carcinoma, dominant oncocytic mixed follicular and macrofollicular variant, 1.3 cm; chronic lymphocytic thyroiditis and mild follicular nodular disease: Thyroid

No pathological diagnosis: Parathyroid, perithyroidal

- Right hemithyroidectomy specimen

ICD-O-3

carcinoma, papillary, follicular variant

8340/3

Site: thyroid, NOS C73.9

Synoptic Data

Procedure:	Right hemithyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 5.9 cm 2.4 cm 1.4 cm Isthmus +/- pyramidal lobe: 1.6 cm 0.8 cm 0.5 cm
Specimen Weight:	10.2 g
Tumor Focality:	Multifocal, ipsilateral

----- DOMINANT TUMOR -----

Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 1.3cm Additional dimension: 1.2 cm Additional dimension: 1.0 cm
Histologic Type:	Papillary carcinoma, follicular variant Papillary carcinoma, macrofollicular variant

per ISS, follicular variant = 100%

[page 2 of 3]
	Papillary carcinoma, oncocytic or oxyphilic variant
	Follicular architecture
	Macrofollicular architecture
	Classical cytomorphology
	Oncocytic or oxyphilic cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Totally encapsulated
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 0.4cm
	Additional dimensions: 0.3 cm
Histologic Type:	Papillary carcinoma, follicular variant
	Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
	Papillary carcinoma, oncocytic or oxyphilic variant
	Follicular architecture
	Classical cytomorphology
	Oncocytic or oxyphilic cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assigned
	Number of regional lymph nodes examined: 0
	Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease
	Thyroiditis
	Parathyroid gland(s), within normal limits

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

verified by:

Electronically

Gross Description

1. The specimen labeled with the patient's name and as "Right Hemi thyroid stitch right upper lobe", consists of a right hemithyroidectomy specimen that is oriented with a suture and weighs 10.2 g. The lobe measures 5.9 cm SI x 2.4 cm ML x 1.4 cm AP and the isthmus measures 1.6 SI

[page 3 of 3]
x 0.8 cm ML x 0.5 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or no lymph nodes are identified grossly. The mid right lobe contains one well delineated nodule that measures 1.3 cm SI x 1.2 cm ML x 1.0 cm AP. The cut surface of the nodule has a variegated brown tan color, solid and firm. A second nodule is identified on the inferior pole measuring 0.4 SI x 0.3 ML x 0.3 cm AP. The remainder of the thyroid tissue is brown in color homogeneous and grossly unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-J lobe, superior to inferior

1K isthmus

Source: NCI Genomic Data Commons file 90e8b9c4-1b03-45b0-b7b2-d5800fd7e3dd (TCGA-EM-A2OW.2BFED855-C6EB-479B-A359-2BE4139D045A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).